Somatic mutation profile of tumor specimen TCGA-KP-A3W4-01A (aliquot TCGA-KP-A3W4-01A-11D-A228-09) from TCGA case TCGA-KP-A3W4, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 63.5 years (23,200 days).
Specimen TCGA-KP-A3W4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eaba9cac-a0a2-4197-a289-840c60c7d7f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KP-A3W4-10A (Blood Derived Normal), aliquot TCGA-KP-A3W4-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd92f3e9-5c17-4bc9-ae25-c6033996ec32

The open-access MAF lists 53 somatic variants for this specimen: 44 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 8, Nonsense Mutation 5, Frame Shift Del 3, Frame Shift Ins 1, Translation Start Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1625A>T p.E542V | Missense Mutation (SNP) | VAF 20/50 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1057519927, COSV55876800, COSV55881194, COSV55893680; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.159G>A p.W53* | Nonsense Mutation (SNP) | VAF 21/29 reads (72%) | hotspot (GDC flag); catalogued as rs1064794618, COSV52751414, COSV53223969, COSV53499187; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASTN2 | c.1752del p.R584Sfs*102 (on ENST00000313400 / NM_001365069.1; = p.R533Sfs*102 on NM_014010.5) | Frame Shift Del (DEL) | VAF 10/18 reads (56%) | catalogued as COSV57809025; called by mutect2, varscan2
- ATP4A | c.791C>G p.T264S | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.029); catalogued as COSV99382029; called by muse, mutect2
- BTNL2 | c.670G>A p.V224I | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs760675404, COSV66630953; called by muse, mutect2, varscan2
- CACNA1B | c.1954G>A p.A652T | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53137439; called by muse, mutect2, varscan2
- CDK12 | c.1059G>C p.M353I | Missense Mutation (SNP) | VAF 443/464 reads (95%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV101420302, COSV71002435; called by muse, mutect2, varscan2
- CDK12 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 237/247 reads (96%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as rs1245449401, COSV101420303, COSV70999322; called by muse, varscan2
- CDK12 | c.1464G>C p.E488D | Missense Mutation (SNP) | VAF 334/355 reads (94%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV101420304; called by muse, varscan2
- CLPP | c.373G>T p.V125L | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV99832131; called by muse, mutect2, varscan2
- CTLA4 | c.417C>G p.Y139* | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | catalogued as COSV99865054; called by muse, mutect2, varscan2
- DIPK1B | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs549609567, COSV63037959; called by muse, mutect2, varscan2
- FLI1 | c.350T>G p.M117R | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.903); catalogued as COSV99857312; called by muse, mutect2
- HIVEP1 | c.8113G>T p.V2705L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.24); catalogued as COSV101044561, COSV65103881; called by muse, mutect2, varscan2
- IGBP1 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV100642875; called by muse, mutect2, varscan2
- IGFBP5 | c.667G>T p.G223* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as COSV52082927, COSV52083151; called by muse, mutect2, varscan2
- INPP5D | c.1451C>T p.T484M (on ENST00000445964 / NM_001017915.3; = p.T483M on NM_005541.5) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs376107758; called by muse, mutect2, varscan2
- INVS | c.861C>G p.S287R | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); catalogued as COSV99316944; called by muse, mutect2, varscan2
- ITGB4 | c.4106C>T p.T1369I | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); catalogued as rs866480528, COSV99563182; called by muse, mutect2
- JAK1 | c.3403C>T p.Q1135* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as COSV99604712; called by muse, mutect2, varscan2
- KIF14 | c.1978T>C p.W660R | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1219620645, COSV100950577; called by muse, mutect2, varscan2
- LAMA1 | c.2156C>G p.S719C | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101054697; called by muse, mutect2
- MIB2 | c.2317C>T p.R773C | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs371873507, COSV61542659; called by muse, mutect2, varscan2
- MUC4 | c.13251G>C p.E4417D (on ENST00000463781 / NM_018406.7; = p.E181D on NM_004532.6) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV100203273; called by muse, mutect2, varscan2
- NAGLU | c.1422G>T p.W474C | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99863927; called by muse, varscan2
- NEUROD4 | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as COSV99669676; called by muse, mutect2, varscan2
- NF1 | c.3640A>G p.M1214V | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.812); catalogued as CM087529, COSV62215782; called by muse, mutect2, varscan2
- NIN | c.1771C>T p.H591Y | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV99811228; called by muse, mutect2, varscan2
- P2RY8 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV101183928; called by muse, mutect2, varscan2
- PAPOLG | c.1298T>C p.V433A | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.16); catalogued as rs1240329643, COSV99474380; called by muse, mutect2, varscan2
- PCNX3 | c.233A>G p.N78S | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.479); catalogued as rs373996709; called by muse, mutect2, varscan2
- RIPPLY1 | c.107G>T p.S36I | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.121); catalogued as COSV99343586; called by muse, mutect2, varscan2
- RMND5A | c.875C>A p.A292E | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99373550; called by muse, mutect2
- RPTOR | c.2815G>T p.D939Y | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV60805328; called by muse, mutect2, varscan2
- SIDT2 | c.1318C>T p.R440C | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99637019; called by muse, mutect2, varscan2
- SLC6A19 | c.1421C>T p.T474M | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.426); catalogued as rs202126249, COSV58672690; called by muse, mutect2, varscan2
- THEG | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs1416453751, COSV61074919; called by muse, mutect2, varscan2
- TRIM32 | c.1410C>A p.S470R | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV100524020; called by muse, mutect2, varscan2
- USP11 | c.343G>A p.A115T (on ENST00000218348; = p.A72T on NM_001371072.1) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as COSV99510602; called by muse, mutect2, varscan2
- WDR88 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.125); catalogued as rs772340255, COSV63451012, COSV63452074; called by muse, mutect2, varscan2
- ZNF777 | c.1942A>G p.K648E | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99924940; called by muse, mutect2, varscan2
- TAS2R10 | c.307dup p.S103Kfs*41 | Frame Shift Ins (INS) | VAF 5/16 reads (31%) | called by mutect2, pindel, varscan2
- TMEM63A | c.2051del p.F684Sfs*9 | Frame Shift Del (DEL) | VAF 18/54 reads (33%) | called by mutect2, pindel, varscan2
- ZNF84 | c.2211del p.K737Nfs*11 | Frame Shift Del (DEL) | VAF 16/59 reads (27%) | called by mutect2, pindel, varscan2
- DPP6 | c.48G>C p.V16= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV101341053; called by muse, mutect2, varscan2
- ELF4 | c.369G>C p.S123= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as COSV100257067, COSV57452072; called by muse, mutect2, varscan2
- FSTL5 | c.825C>A p.T275= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as rs1213339490, COSV100051970; called by muse, mutect2, varscan2
- LGALS3BP | c.1276C>A p.R426= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV99431302; called by muse, mutect2, varscan2
- PCDHA2 | c.2106C>T p.I702= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as rs1257564144, COSV65367389; called by muse, mutect2, varscan2
- STAC2 | c.393C>T p.I131= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs774755292, COSV100336245; called by muse, mutect2, varscan2
- TEX11 | c.642C>G p.L214= (on ENST00000344304; = p.L199= on NM_031276.3) | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV100721252; called by muse, mutect2, varscan2
- TG | c.7938G>A p.L2646= | Silent (SNP) | VAF 28/121 reads (23%) | catalogued as COSV55083978, COSV99598609; called by muse, mutect2, varscan2
- MIR509-3 | n.12C>T | RNA (SNP) | VAF 28/109 reads (26%) | called by muse, mutect2, varscan2
